Somatic mutation profile of tumor specimen TCGA-18-3409-01A (aliquot TCGA-18-3409-01A-01D-0983-08) from TCGA case TCGA-18-3409, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.3 years (27,154 days).
Specimen TCGA-18-3409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18e45dec-54d0-4600-b636-47781d9842c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3409-11A (Solid Tissue Normal), aliquot TCGA-18-3409-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf2ada35-4f78-44f0-9369-2a6f1e5824e1

The open-access MAF lists 3,650 somatic variants for this specimen: 2,340 protein-altering or splice-affecting, 1,219 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,129, Silent 1,219, Nonsense Mutation 134, Intron 37, RNA 33, Splice Region 32, Splice Site 32, Frame Shift Del 10, 3'UTR 8, 3'Flank 5, 5'Flank 5, 5'UTR 3.

Variants (750 of 3,650; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as rs746887961, COSV66059632; called by muse, mutect2
- CARD11 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67797089; called by muse, mutect2, varscan2
- CDKN2A | c.458-2A>T p.X153_splice | Splice Site (SNP) | VAF 16/27 reads (59%) | hotspot (GDC flag); catalogued as CS127045, CS1414343, COSV58683256, COSV58703271, COSV58726067; called by muse, mutect2, varscan2
- COL3A1 | c.2959G>A p.G987S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779583, CM1412682, COSV58592673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 66/205 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- DNAI1 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs79833450, CM011938, COSV99647140; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IL17RA | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1057518745, COSV60053486; ClinVar: pathogenic; called by mutect2, varscan2
- JAK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758959409, COSV71685371; ClinVar: likely pathogenic; called by mutect2, varscan2
- LAMC1 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV51152730; called by muse, mutect2, varscan2
- NOTCH2 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs312262795, CM1110712, COSV56701378, COSV99864693; ClinVar: pathogenic; called by mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs397516539, CM065450, CM156349, COSV63686290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV62790795; called by muse, mutect2, varscan2
- ABCA13 | c.438A>G p.P146= | Splice Region (SNP) | VAF 45/174 reads (26%) | catalogued as rs1243371473, COSV70034056; called by muse, mutect2, varscan2
- ABCA13 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1435332581, COSV70027386; called by muse, mutect2, varscan2
- ABCA13 | c.4550C>T p.S1517F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as rs1396325137, COSV70034151; called by muse, mutect2, varscan2
- ABCA13 | c.14728G>A p.V4910M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68948664; called by muse, mutect2, varscan2
- ABCA3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1185200028, COSV57056232; called by muse, mutect2, varscan2
- ABCA5 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1005546917, COSV67017736; called by muse, mutect2, varscan2
- ABCB1 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55955895; called by muse, mutect2, varscan2
- ABCB10 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60622210; called by muse, mutect2, varscan2
- ABCB10 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60622223; called by muse, mutect2, varscan2
- ABCB11 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594493, COSV55595120; called by muse, mutect2, varscan2
- ABCB4 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55937811; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCC12 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV60915586; called by muse, mutect2, varscan2
- ABCC5 | c.941T>A p.I314N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV55592987; called by muse, mutect2, varscan2
- ABCC5 | c.940A>T p.I314F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV55592995; called by muse, mutect2, varscan2
- ABCC9 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53977702; called by muse, mutect2, varscan2
- ABCD2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100429850, COSV58049378; called by muse, mutect2, varscan2
- ABCD2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs766162060, COSV58053060; called by muse, mutect2, varscan2
- ABL2 | c.1120C>T p.R374* (on ENST00000502732 / NM_007314.4; = p.R359* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as rs780176171, COSV61013538; called by muse, mutect2, varscan2
- ABRA | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61732920; called by muse, mutect2, varscan2
- AC004593.2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772321778, COSV56096286; called by muse, mutect2, varscan2
- AC004593.2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV56096298; called by muse, mutect2, varscan2
- AC092143.1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV59248224, COSV59248676; called by muse, mutect2, varscan2
- AC098582.1 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52022117; called by muse, mutect2, varscan2
- AC100868.1 | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.272); catalogued as COSV51846079; called by muse, varscan2
- AC100868.1 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV51846096; called by muse, mutect2
- ACACB | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs756027386, COSV58139314; called by muse, mutect2, varscan2
- ACACB | c.6377G>A p.G2126E | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58139324; called by muse, mutect2, varscan2
- ACAD10 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58156964; called by muse, mutect2, varscan2
- ACAN | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61364153; called by muse, mutect2, varscan2
- ACOT8 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54170328; called by muse, mutect2, varscan2
- ACSBG1 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV51908174; called by muse, mutect2, varscan2
- ACSM2A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV54585410; called by muse, mutect2, varscan2
- ACSM2A | c.1561G>A p.E521K (on ENST00000219054; = p.E442K on NM_001308169.2) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV54583673; called by muse, varscan2
- ACSM2B | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 52/203 reads (26%) | catalogued as rs374858896; called by muse, mutect2, varscan2
- ACSM4 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV68068408; called by muse, mutect2, varscan2
- ACSS3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54095391; called by muse, mutect2, varscan2
- ACTG1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59510377; called by muse, mutect2, varscan2
- ACTL9 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100185027, COSV61006502; called by muse, mutect2, varscan2
- ACTN1 | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV51994583; called by mutect2, varscan2
- ACTN3 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV59749570; called by muse, mutect2, varscan2
- ACTN4 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53147795; called by mutect2, varscan2
- ACTR6 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51842357; called by muse, mutect2, varscan2
- ACVR1B | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57778335; called by muse, mutect2, varscan2
- ACVR2A | c.556T>A p.L186I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV54025332; called by muse, mutect2, varscan2
- ADAM18 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.965); catalogued as COSV55847819; called by muse, varscan2
- ADAM18 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55850536; called by muse, varscan2
- ADAM18 | c.1259A>C p.Y420S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV55850545; called by muse, mutect2, varscan2
- ADAM33 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62935664; called by muse, mutect2, varscan2
- ADAM7 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.191); catalogued as COSV51537081; called by muse, mutect2, varscan2
- ADAMTS12 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs760038469, COSV61268814; called by muse, mutect2, varscan2
- ADAMTS17 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as rs532333138, COSV51485946; called by muse, mutect2, varscan2
- ADAMTS17 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs767903685, COSV51485956; called by muse, mutect2, varscan2
- ADAMTS17 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.321); catalogued as COSV51485978; called by muse, mutect2, varscan2
- ADAMTS19 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV50764269; called by muse, mutect2, varscan2
- ADAMTS20 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs191978295, COSV67134703; called by mutect2, varscan2
- ADAMTS3 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as COSV54389326, COSV54396001; called by muse, mutect2, varscan2
- ADAMTS4 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63490586; called by muse, mutect2, varscan2
- ADAMTS6 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV66861791; called by muse, mutect2, varscan2
- ADAMTS7 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66308347; called by muse, mutect2
- ADAMTS9 | c.3601G>A p.G1201S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55785068; called by muse, mutect2, varscan2
- ADAMTS9 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV55785091; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52819207; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs3004643, COSV65889692; called by muse, mutect2, varscan2
- ADCY8 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV53915259; called by muse, varscan2
- ADCY8 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs376569097; called by muse, varscan2
- ADCYAP1R1 | c.1046+1G>C p.X349_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV58444965; called by muse, mutect2, varscan2
- ADGRF5 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV51936592; called by muse, varscan2
- ADGRL1 | c.3146G>A p.W1049* (on ENST00000340736 / NM_001008701.3; = p.W1044* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1186349522, COSV100529773, COSV61565497; called by muse, mutect2, varscan2
- ADGRV1 | c.5308T>C p.Y1770H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67989588; called by muse, mutect2, varscan2
- ADIPOR2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs201727993, COSV63947011, COSV63947605; called by muse, mutect2, varscan2
- ADORA2A | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58379601; called by muse, mutect2, varscan2
- ADORA2A | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58379607; called by muse, mutect2
- ADRA1B | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60702842; called by muse, mutect2, varscan2
- ADRB2 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV60005251; called by muse, mutect2, varscan2
- AFF1 | c.3629C>T p.P1210L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV57121655; called by muse, mutect2, varscan2
- AFTPH | c.2624G>A p.R875K (on ENST00000238855 / NM_203437.3; = p.R847K on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53219577; called by muse, mutect2, varscan2
- AGAP2 | c.2134C>T p.P712S (on ENST00000547588 / NM_001122772.2; = p.P376S on NM_014770.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.237); catalogued as COSV57729781; called by muse, mutect2, varscan2
- AGBL1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.105); catalogued as COSV69804449; called by muse, mutect2, varscan2
- AGPAT5 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53446410; called by muse, mutect2, varscan2
- AHNAK | c.9409C>T p.P3137S | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57220338; called by muse, mutect2, varscan2
- AHNAK | c.6505G>A p.G2169R | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV57220367; called by muse, mutect2, varscan2
- AHNAK2 | c.15919C>T p.P5307S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV60921347; called by muse, mutect2, varscan2
- AHNAK2 | c.13099C>T p.P4367S | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV60921362; called by muse, mutect2, varscan2
- AHNAK2 | c.10717G>A p.G3573S | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.629); catalogued as rs1247010955, COSV60921369; called by muse, mutect2, varscan2
- AIFM2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as rs752400502, COSV57158868; called by muse, mutect2, varscan2
- AIMP2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs746796665, COSV52240932; called by muse, mutect2, varscan2
- AIPL1 | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV51507769; called by muse, mutect2, varscan2
- AK9 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs775310575, COSV69851307; called by muse, mutect2, varscan2
- AKAP12 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV53577962; called by muse, mutect2, varscan2
- AKAP13 | c.4679C>T p.P1560L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63363258; called by muse, mutect2, varscan2
- AKAP7 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV63505426; called by muse, mutect2, varscan2
- AKAP9 | c.5446C>T p.H1816Y (on ENST00000359028; = p.H1784Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.17); catalogued as COSV62339665; called by muse, mutect2, varscan2
- AKR1D1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867274244, COSV54338660; called by muse, mutect2, varscan2
- AKT3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV55622695; called by muse, mutect2, varscan2
- AL035461.3 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.443); catalogued as COSV66651665; called by muse, mutect2, varscan2
- AL035461.3 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as rs371425827; called by muse, mutect2, varscan2
- AL358113.1 | c.3281C>T p.P1094L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs747689606, COSV55269654; called by muse, mutect2, varscan2
- ALB | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.59); catalogued as rs1445148767, COSV55738215; called by muse, mutect2, varscan2
- ALB | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs74826639, CM930015, COSV55739833; ClinVar: other; called by muse, mutect2, varscan2
- ALDH1L1 | c.2254C>T p.H752Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV56416374; called by muse, mutect2, varscan2
- ALK | c.4462G>A p.E1488K | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV66576814; called by muse, mutect2, varscan2
- ALLC | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 28/111 reads (25%) | catalogued as rs201366958; called by muse, varscan2
- ALMS1 | c.11507C>T p.P3836L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs370100719, COSV52514356; called by muse, mutect2, varscan2
- ALOX15B | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as COSV66479732; called by muse, mutect2, varscan2
- ALPK2 | c.4397G>A p.R1466K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV64494490; called by muse, mutect2, varscan2
- ALPL | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1291792579, COSV66380148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALX1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57491817; called by muse, mutect2, varscan2
- AMER3 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs577463247, COSV58466798; called by muse, mutect2, varscan2
- AMPH | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57745073, COSV57748302; called by muse, mutect2, varscan2
- ANGEL1 | c.1593G>A p.M531I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51874224, COSV99200333; called by muse, varscan2
- ANGPTL1 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160677351, COSV52367086; called by muse, mutect2, varscan2
- ANGPTL1 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV52367098; called by muse, mutect2, varscan2
- ANGPTL1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52367115; called by muse, mutect2, varscan2
- ANK2 | c.8291G>A p.R2764K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV52172467; called by muse, mutect2, varscan2
- ANK3 | c.5903T>G p.V1968G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV55067476; called by muse, mutect2, varscan2
- ANKFN1 | c.1316+1G>A p.X439_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59452449; called by muse, mutect2, varscan2
- ANKRD17 | c.3808C>T p.L1270F | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100429419; called by muse, mutect2, varscan2
- ANKRD24 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53672778; called by muse, varscan2
- ANKRD30A | c.1521G>A p.M507I (on ENST00000611781; = p.M451I on NM_052997.2) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs564319804, COSV64614781; called by muse, mutect2, varscan2
- ANKRD50 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1382943401, COSV72385901; called by muse, mutect2, varscan2
- ANKS1B | c.2739G>A p.M913I (on ENST00000547776 / NM_152788.4; = p.M139I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV60367654; called by muse, mutect2
- ANO5 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61083995, COSV61087405; called by muse, mutect2, varscan2
- ANXA5 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56639456; called by muse, mutect2, varscan2
- AP3M2 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1467751006, COSV51529611; called by muse, mutect2, varscan2
- APBA2 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV68792868; called by muse, mutect2
- APBA2 | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68792876; called by muse, mutect2, varscan2
- APBB1IP | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV63303128; called by muse, mutect2, varscan2
- APLNR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV57243345; called by muse, mutect2, varscan2
- APMAP | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54175267; called by muse, mutect2, varscan2
- APOB | c.7537C>T p.R2513* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs146538280, CM910035; called by muse, mutect2, varscan2
- APOB | c.7216G>T p.E2406* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV51942597; called by muse, mutect2, varscan2
- APOF | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1422902992, COSV58476282; called by muse, mutect2, varscan2
- AQP4 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67218974; called by muse, mutect2, varscan2
- AQR | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV50040181; called by muse, mutect2, varscan2
- ARAP3 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV53352164; called by muse, mutect2
- ARAP3 | c.1043T>A p.F348Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53352176; called by muse, mutect2, varscan2
- ARHGAP12 | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60964539; called by muse, mutect2, varscan2
- ARHGAP28 | c.697A>T p.S233C (on ENST00000383472 / NM_001366230.1; = p.S74C on NM_001010000.3) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV51641327; called by muse, mutect2, varscan2
- ARHGAP28 | c.1040C>T p.S347F (on ENST00000383472 / NM_001366230.1; = p.S188F on NM_001010000.3) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs774706809, COSV51641345; called by muse, mutect2, varscan2
- ARHGAP32 | c.5998G>A p.D2000N (on ENST00000310343 / NM_001378025.1; = p.D1651N on NM_014715.4) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV59851265; called by muse, mutect2, varscan2
- ARHGAP32 | c.5527G>A p.G1843R (on ENST00000310343 / NM_001378025.1; = p.G1494R on NM_014715.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs371147218; called by muse, mutect2, varscan2
- ARHGAP33 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1380490288, COSV50132401; called by muse, mutect2, varscan2
- ARHGAP35 | c.2548C>T p.R850W | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV68329681; called by muse, mutect2, varscan2
- ARHGAP9 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs779766283, COSV62723603; called by mutect2, varscan2
- ARHGEF17 | c.5731G>A p.D1911N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55234514; called by muse, mutect2, varscan2
- ARHGEF25 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.085); catalogued as COSV54088202; called by muse, mutect2, varscan2
- ARID1A | c.6311C>T p.S2104F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1322532917, COSV61378968; called by muse, mutect2, varscan2
- ARID1B | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs143370913, COSV51669511; called by muse, mutect2, varscan2
- ARID2 | c.4591C>T p.P1531S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57608825; called by muse, mutect2, varscan2
- ARL6IP1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58614614; called by muse, mutect2, varscan2
- ARL6IP1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV58614617; called by muse, mutect2, varscan2
- ARMC2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs753358737, COSV52900866; called by muse, mutect2, varscan2
- ARMT1 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV66178791; called by muse, mutect2, varscan2
- ARRDC4 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51419677; called by muse, mutect2, varscan2
- ARSA | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53350785, COSV53350894; called by muse, mutect2, varscan2
- ARSF | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63840226; called by muse, mutect2, varscan2
- ART3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61914722; called by muse, mutect2, varscan2
- ASB4 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs267601648, COSV57946501; called by muse, mutect2, varscan2
- ASB5 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56672320, COSV56675559; called by muse, mutect2, varscan2
- ASH1L | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64210331; called by muse, mutect2, varscan2
- ASIC2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV56765631; called by muse, mutect2, varscan2
- ASIC2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV63316015; called by muse, mutect2, varscan2
- ASIC4 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs1459689251, COSV61732459; called by muse, mutect2, varscan2
- ASNS | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV51553838; called by muse, mutect2, varscan2
- ASNS | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs753038843, COSV51550570; called by muse, mutect2, varscan2
- ASPH | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV65245614; called by muse, mutect2, varscan2
- ASPM | c.9787T>A p.Y3263N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV54129908; called by muse, mutect2, varscan2
- ASPM | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433098788, COSV54133208; called by muse, mutect2, varscan2
- ASPM | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54133219; called by muse, mutect2, varscan2
- ASXL1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs751518063, COSV60106744; called by muse, mutect2, varscan2
- ASXL1 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV60113068; called by muse, mutect2, varscan2
- ATAD1 | c.880T>C p.F294L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV57757674; called by muse, mutect2, varscan2
- ATAD2 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV54883446; called by muse, mutect2, varscan2
- ATAD2B | c.2718T>A p.F906L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53201965; called by muse, mutect2, varscan2
- ATG2B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63421577; called by muse, mutect2, varscan2
- ATN1 | c.2917C>T p.R973* | Nonsense Mutation (SNP) | VAF 26/43 reads (60%) | catalogued as COSV63111160, COSV63113007; called by muse, mutect2, varscan2
- ATP10B | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.197); catalogued as COSV59157556; called by muse, mutect2, varscan2
- ATP12A | c.2927C>A p.S976* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54519164; called by muse, mutect2, varscan2
- ATP13A3 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs758032591, COSV55466825; called by mutect2, varscan2
- ATP13A5 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV53232158; called by muse, mutect2, varscan2
- ATP1A4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs748470369, COSV63625578; called by muse, mutect2, varscan2
- ATP2A3 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs1321308248, COSV59231495; called by muse, mutect2, varscan2
- ATP4A | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52869438, COSV99381947; called by muse, mutect2, varscan2
- ATP6V0A2 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV57748579; called by muse, mutect2, varscan2
- ATP7A | c.2538T>A p.D846E | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58449312; called by muse, mutect2, varscan2
- ATP9B | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56955261; called by muse, mutect2, varscan2
- ATR | c.2488C>A p.H830N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63388365; called by muse, mutect2
- ATRN | c.1654T>A p.F552I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV53530261; called by muse, mutect2, varscan2
- ATXN10 | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53298375; called by muse, mutect2, varscan2
- AUTS2 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV61415140; called by muse, mutect2, varscan2
- AVEN | c.800A>C p.D267A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV60735702; called by muse, mutect2, varscan2
- AXDND1 | c.1682A>T p.N561I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV62644869; called by muse, mutect2, varscan2
- B4GALT4 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63296115; called by muse, mutect2, varscan2
- B4GALT6 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52703277, COSV52704188; called by muse, mutect2, varscan2
- BAAT | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52289920; called by muse, mutect2, varscan2
- BAG1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65651729; called by muse, mutect2, varscan2
- BAIAP3 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs754381578, COSV60981751; called by muse, mutect2, varscan2
- BARX2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs1370278752, COSV55651222; called by muse, mutect2, varscan2
- BAZ1A | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62410998; called by muse, varscan2
- BAZ1A | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV62411005; called by muse, varscan2
- BAZ1B | c.2269C>T p.L757F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59992376; called by muse, mutect2, varscan2
- BAZ2B | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58604827; called by muse, mutect2, varscan2
- BBX | c.2810C>T p.S937F (on ENST00000325805 / NM_001142568.3; = p.S907F on NM_020235.7) | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57882925; called by muse, mutect2, varscan2
- BCAN | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61257853, COSV61258565; called by muse, mutect2, varscan2
- BCL2L13 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs766203253, COSV58226582; called by muse, mutect2, varscan2
- BCL9L | c.4111C>G p.P1371A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV52686541; called by muse, mutect2, varscan2
- BCO1 | c.80G>A p.W27* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as COSV50730698; called by muse, varscan2
- BCR | c.3722C>T p.S1241F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV59933489; called by mutect2, varscan2
- BIRC6 | c.12379G>A p.E4127K | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV70202437; called by muse, mutect2, varscan2
- BLID | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.973); catalogued as COSV73340284; called by muse, mutect2, varscan2
- BNIP1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV51571146; called by muse, mutect2, varscan2
- BNIPL | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs141131792; called by muse, mutect2, varscan2
- BOC | c.1702+1G>T p.X568_splice | Splice Site (SNP) | VAF 29/68 reads (43%) | catalogued as COSV56354233; called by muse, mutect2, varscan2
- BPIFA2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267605885, COSV53611599; called by muse, mutect2, varscan2
- BPIFA2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as rs766850220, COSV53611608; called by muse, mutect2, varscan2
- BPTF | c.2660G>A p.G887E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58841085; called by muse, mutect2, varscan2
- BRCA1 | c.1574T>C p.V525A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs879253902, COSV58793834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6602C>T p.S2201F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV66457298; called by muse, mutect2, varscan2
- BRD7 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as rs773781182, COSV67159332; called by muse, mutect2, varscan2
- BRDT | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV62865846; called by muse, mutect2
- BRIP1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV52002720; called by muse, mutect2, varscan2
- BTNL2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66631182; called by muse, mutect2, varscan2
- BTNL9 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV59797153; called by muse, mutect2, varscan2
- BUD13 | c.1844G>A p.S615N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52767627; called by muse, varscan2
- C10orf90 | c.2087G>A p.R696K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs1178487614, COSV52958635; called by muse, varscan2
- C10orf90 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV52949999; called by muse, mutect2, varscan2
- C16orf89 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs561235172, COSV60124766; called by muse, mutect2, varscan2
- C19orf44 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs777127184, COSV55613102; called by muse, mutect2, varscan2
- C19orf47 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs377039602; called by mutect2, varscan2
- C19orf47 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV63509986; called by muse, mutect2, varscan2
- C1QA | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.902); catalogued as rs767339831, COSV65889843; called by mutect2, varscan2
- C1QB | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59245673; called by muse, mutect2, varscan2
- C1QTNF2 | c.485C>T p.P162L (on ENST00000393975; = p.P117L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.442); catalogued as COSV67432961; called by muse, mutect2, varscan2
- C1orf87 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64597797; called by muse, mutect2, varscan2
- C2orf78 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV68518364; called by muse, mutect2, varscan2
- C3orf20 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV53786838; called by muse, mutect2
- C3orf56 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67756368; called by muse, mutect2, varscan2
- C4BPA | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV65536811; called by muse, mutect2, varscan2
- C6orf62 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV65290872; called by muse, mutect2, varscan2
- C8orf74 | c.713A>C p.Q238P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV58754828; called by muse, mutect2
- CA7 | c.238+1G>A p.X80_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs1440618013, COSV58156843; called by muse, mutect2, varscan2
- CABP1 | c.691C>T p.R231* (on ENST00000316803 / NM_001033677.1; = p.R28* on NM_004276.5) | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV56459415; called by muse, mutect2, varscan2
- CABP2 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV53709205; called by muse, mutect2, varscan2
- CACHD1 | c.2377C>T p.H793Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51556417; called by muse, mutect2, varscan2
- CACNA1A | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs867125827, COSV64202972; called by muse, mutect2, varscan2
- CACNA1E | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs369308237; called by muse, mutect2, varscan2
- CACNA1G | c.5239G>A p.G1747R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61731690; called by muse, mutect2, varscan2
- CACNA1I | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as rs1459485626, COSV60812950; called by muse, mutect2, varscan2
- CAD | c.1004T>C p.F335S | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53028865; called by muse, mutect2, varscan2
- CALCRL | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV66475988; called by muse, mutect2, varscan2
- CALCRL | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66475990, COSV66476528; called by mutect2, varscan2
- CAMK2D | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56434388; called by muse, mutect2, varscan2
- CAMTA1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1167802383, COSV57902763; called by muse, mutect2, varscan2
- CAMTA1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57911883; called by muse, mutect2, varscan2
- CAP2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57734278; called by muse, mutect2, varscan2
- CAPN10 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs763737919, COSV54377708; called by mutect2, varscan2
- CAPN11 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV67238344; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CARF | c.2057T>A p.L686H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV57548559; called by muse, mutect2, varscan2
- CARNMT1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755155692, COSV100961764, COSV65194013; called by muse, mutect2, varscan2
- CARNS1 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57047968; called by muse, mutect2, varscan2
- CASD1 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV51973753; called by muse, mutect2, varscan2
- CASP7 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61882366; called by muse, mutect2, varscan2
- CASR | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV56139088; called by muse, mutect2, varscan2
- CATSPERD | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs1165124030, COSV58466124; called by muse, mutect2, varscan2
- CBL | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV50645561; called by muse, mutect2, varscan2
- CBX2 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs375170872; called by muse, mutect2, varscan2
- CBY2 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1446565317, COSV100137730, COSV60117749; called by muse, mutect2, varscan2
- CCAR1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV56271467; called by muse, mutect2, varscan2
- CCAR2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51516015; called by muse, mutect2, varscan2
- CCDC105 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762965086, COSV52964626; called by mutect2, varscan2
- CCDC105 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52964633; called by muse, mutect2, varscan2
- CCDC141 | c.3556G>A p.D1186N | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV55377080; called by muse, mutect2, varscan2
- CCDC141 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.108); catalogued as COSV55369150, COSV55371057; called by muse, mutect2, varscan2
- CCDC146 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV53551138; called by muse, mutect2, varscan2
- CCDC157 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57840569; called by muse, mutect2, varscan2
- CCDC158 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1350535297, COSV66355379; called by muse, mutect2, varscan2
- CCDC178 | c.1986G>A p.M662I (on ENST00000383096 / NM_001105528.3; = p.M624I on NM_198995.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs867565267, COSV55759521; called by muse, mutect2, varscan2
- CCDC178 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.073); catalogued as COSV55782954; called by muse, mutect2, varscan2
- CCDC18 | c.3584C>T p.S1195F (on ENST00000343253 / NM_001306076.1; = p.S1196F on NM_206886.4) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV58145178; called by muse, mutect2, varscan2
- CCDC186 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV65161613; called by muse, mutect2, varscan2
- CCDC32 | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV63635210; called by muse, mutect2, varscan2
- CCDC65 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs145334864; called by muse, mutect2, varscan2
- CCDC70 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs1566372962, COSV54430543; called by muse, mutect2, varscan2
- CCDC8 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1008161841, COSV56774006; called by muse, mutect2, varscan2
- CCDC80 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52818179; called by muse, mutect2, varscan2
- CCDC88B | c.3933G>A p.K1311= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV57266937; called by mutect2, varscan2
- CCN2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); catalogued as rs1480590727, COSV63466848; called by muse, mutect2, varscan2
- CCN6 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782354915, COSV57889752; called by muse, mutect2, varscan2
- CCR6 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100551228, COSV59475604; called by muse, mutect2, varscan2
- CCSER2 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.805); catalogued as COSV56507997; called by muse, mutect2, varscan2
- CCT8L2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV63462430; called by muse, mutect2, varscan2
- CCT8L2 | c.80A>G p.E27G | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63463088; called by muse, mutect2, varscan2
- CD109 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54652688; called by muse, mutect2, varscan2
- CD226 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs1358404350, COSV54610640; called by muse, mutect2, varscan2
- CD8B | c.712C>T p.P238S (on ENST00000331469 / NM_172213.4; = p.P208S on NM_172102.4) | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV58926970; called by muse, mutect2, varscan2
- CDADC1 | c.827T>G p.M276R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51912389; called by muse, mutect2, varscan2
- CDC20B | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57050664; called by muse, mutect2, varscan2
- CDH10 | c.2296C>T p.R766* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100050202, COSV52579639, COSV52582699; called by muse, mutect2, varscan2
- CDH2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286426; called by muse, mutect2, varscan2
- CDH23 | c.8455C>T p.P2819S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV56474809; called by muse, mutect2, varscan2
- CDH4 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs865813105, COSV64662525; called by muse, varscan2
- CDH7 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59883694; called by muse, mutect2, varscan2
- CDH8 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV54871412; called by muse, varscan2
- CDH8 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV54872935; called by muse, mutect2, varscan2
- CDHR1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as CM153052, COSV60564251; called by muse, mutect2, varscan2
- CDK10 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58415221; called by muse, mutect2, varscan2
- CDKL2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56734192; called by muse, mutect2, varscan2
- CDON | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as rs754733084, COSV54999869; called by muse, mutect2, varscan2
- CDX4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as COSV65171742; called by muse, mutect2, varscan2
- CEACAM3 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782711240, COSV55762264; called by muse, mutect2, varscan2
- CEACAM7 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | catalogued as COSV50073616; called by muse, mutect2, varscan2
- CEBPZ | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52207254; called by muse, mutect2, varscan2
- CELF3 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51882375; called by muse, mutect2, varscan2
- CELSR1 | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs372128480; called by muse, mutect2, varscan2
- CELSR2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54775393; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CEMIP2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV65487494; called by muse, mutect2, varscan2
- CENPN | c.664_665del p.L222Tfs*18 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs772745696; called by pindel, varscan2
- CEP104 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV65518152; called by mutect2, varscan2
- CEP164 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as COSV54043438; called by muse, mutect2
- CEP290 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV58353512; called by muse, mutect2, varscan2
- CFAP43 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.245); catalogued as COSV53379311, COSV53381118; called by muse, mutect2, varscan2
- CFAP45 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs1183047386, COSV63649928; called by muse, mutect2, varscan2
- CFAP54 | c.6724+1G>A p.X2242_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as rs1434235034, COSV61573226; called by mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFAP65 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as rs747396715, COSV58563304; called by mutect2, varscan2
- CFAP65 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as rs1487644078, COSV55390906; called by muse, mutect2, varscan2
- CFAP69 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60186761; called by muse, mutect2, varscan2
- CFAP91 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56342386; called by muse, mutect2, varscan2
- CFH | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62778126; called by muse, mutect2, varscan2
- CFH | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as COSV66407548; called by muse, mutect2, varscan2
- CFTR | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM1414310, COSV50069668; called by muse, mutect2, varscan2
- CGNL1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55571056; called by muse, mutect2, varscan2
- CHAF1B | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV58440719; called by muse, varscan2
- CHD5 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); catalogued as rs759025918, COSV52419303; called by muse, mutect2, varscan2
- CHD8 | c.2161C>T p.P721S (on ENST00000646647 / NM_001170629.2; = p.P442S on NM_020920.4) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV67871540; called by muse, mutect2, varscan2
- CHFR | c.848C>T p.T283I (on ENST00000432561 / NM_001161345.1; = p.T242I on NM_018223.2) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57176015; called by muse, mutect2, varscan2
- CHGB | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV66760991; called by muse, varscan2
- CHGB | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV66760996; called by muse, varscan2
- CHIA | c.481G>A p.E161K (on ENST00000343320; = p.E53K on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs866842630, COSV58476663; called by muse, mutect2, varscan2
- CHKA | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55840857; called by muse, mutect2, varscan2
- CHRDL1 | c.893A>G p.N298S (on ENST00000372045; = p.N304S on NM_145234.4) | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.098); catalogued as rs756501889, COSV54326676; called by muse, mutect2, varscan2
- CHRM3 | c.1210A>C p.K404Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as COSV55094478; called by muse, mutect2, varscan2
- CHRM4 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV63126805; called by muse, mutect2, varscan2
- CHRNA1 | c.1127G>T p.R376I (on ENST00000261007 / NM_001039523.3; = p.R351I on NM_000079.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV53681778, COSV53683614; called by muse, mutect2, varscan2
- CHRNA4 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64720359; called by muse, mutect2, varscan2
- CHRNE | c.189G>A p.L63= | Splice Region (SNP) | VAF 46/134 reads (34%) | catalogued as rs768469610, COSV53418858; called by muse, mutect2, varscan2
- CHST4 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58297643; called by muse, mutect2, varscan2
- CIAO2A | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55538791; called by muse, mutect2, varscan2
- CIB3 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1228413239, COSV54165535; called by muse, mutect2, varscan2
- CIT | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 119/244 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV55874687; called by muse, mutect2, varscan2
- CLCN1 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.4); catalogued as COSV58371870; called by muse, mutect2, varscan2
- CLCN2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027524389, COSV55602526; called by muse, mutect2, varscan2
- CLDN10 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV54825073; called by muse, mutect2, varscan2
- CLDN16 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.187); catalogued as COSV53228493; called by muse, mutect2, varscan2
- CLDN4 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs561546540, COSV52896449, COSV99936569; called by muse, mutect2, varscan2
- CLEC4D | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55229639, COSV55230308; called by muse, mutect2, varscan2
- CLEC4M | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV99940623; called by muse, varscan2
- CLEC9A | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV59532930; called by muse, mutect2, varscan2
- CLMN | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV54184594; called by muse, mutect2, varscan2
- CLOCK | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100011840; called by muse, mutect2, varscan2
- CLRN1 | c.521G>A p.G174E (on ENST00000327047 / NM_174878.3; = p.G98E on NM_052995.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.688); catalogued as COSV55806052, COSV55806260; called by muse, mutect2, varscan2
- CLSTN1 | c.1021C>T p.P341S (on ENST00000377298 / NM_001009566.3; = p.P331S on NM_014944.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100790599, COSV63649137; called by muse, mutect2
- CMIP | c.1758C>T p.I586= (on ENST00000537098 / NM_198390.2; = p.I492= on NM_030629.3) | Splice Region (SNP) | VAF 58/157 reads (37%) | catalogued as COSV67699294; called by muse, mutect2, varscan2
- CMTR2 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs761701086, COSV57603863, COSV57605306; called by muse, mutect2, varscan2
- CMYA5 | c.4940G>A p.R1647K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV71407347; called by muse, varscan2
- CMYA5 | c.5000C>T p.S1667F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV71407351, COSV71407685; called by muse, varscan2
- CMYA5 | c.5203G>A p.G1735R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV71407355; called by muse, mutect2, varscan2
- CMYA5 | c.9670C>T p.P3224S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71407361; called by muse, mutect2, varscan2
- CNBD1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373039361; called by muse, mutect2, varscan2
- CNGA1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs776929323, COSV62054359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGA3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs763513739, COSV55625673; called by muse, mutect2, varscan2
- CNKSR2 | c.1092G>A p.R364= | Splice Region (SNP) | VAF 8/18 reads (44%) | catalogued as rs781721463, COSV54253769; called by muse, mutect2, varscan2
- CNMD | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as rs750734938, COSV65033498; called by muse, mutect2, varscan2
- CNOT1 | c.3770C>T p.P1257L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55316867, COSV55319187; called by muse, mutect2, varscan2
- CNOT1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.484); catalogued as rs773593983, COSV57774593; called by muse, mutect2, varscan2
- CNTN1 | c.2482C>T p.H828Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61642071; called by mutect2, varscan2
- CNTN1 | c.2528G>C p.R843P | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61638757, COSV61642076; called by muse, mutect2, varscan2
- CNTN3 | c.2158A>G p.T720A | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV55177069; called by muse, mutect2, varscan2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by mutect2, varscan2
- CNTNAP2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV62140241, COSV62213628; called by muse, mutect2, varscan2
- CNTNAP2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs868783000, COSV62173390; called by muse, mutect2, varscan2
- CNTNAP2 | c.1574A>C p.Q525P | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.522); catalogued as COSV62213638; called by muse, mutect2, varscan2
- CNTNAP4 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs769681418, COSV56671318; called by muse, mutect2, varscan2
- CNTNAP4 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1233988068, COSV56689705; called by muse, mutect2, varscan2
- COBLL1 | c.1564C>T p.P522S (on ENST00000392717; = p.P484S on NM_014900.5) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV52071269; called by muse, mutect2, varscan2
- COCH | c.1042G>A p.E348K (on ENST00000216361 / NM_001347720.1; = p.E283K on NM_004086.3) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs1224796113, COSV53551713; called by muse, mutect2, varscan2
- COG2 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV64187453; called by muse, mutect2, varscan2
- COG4 | c.1479C>T p.F493= | Splice Region (SNP) | VAF 15/65 reads (23%) | catalogued as COSV60423802; called by muse, mutect2, varscan2
- COL11A1 | c.3574G>A p.G1192R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62188987; called by muse, mutect2, varscan2
- COL11A2 | c.3602G>A p.G1201E (on ENST00000341947 / NM_080680.3; = p.G1094E on NM_080679.2) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59499126; called by muse, mutect2, varscan2
- COL14A1 | c.2349+1G>A p.X783_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV52860328; called by muse, mutect2, varscan2
- COL19A1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59578306; called by muse, mutect2, varscan2
- COL19A1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59566707, COSV59578320; called by muse, mutect2, varscan2
- COL1A1 | c.3092G>A p.G1031D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56807030; called by muse, mutect2, varscan2
- COL1A1 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56807039; called by muse, mutect2, varscan2
- COL1A2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51961292; called by muse, mutect2, varscan2
- COL1A2 | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51960253; called by muse, mutect2, varscan2
- COL1A2 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV51961311; called by muse, mutect2, varscan2
- COL22A1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775776355, COSV57328143; called by muse, mutect2, varscan2
- COL23A1 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV66793345; called by muse, mutect2, varscan2
- COL24A1 | c.1037A>T p.N346I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100993559, COSV65309230; called by muse, mutect2, varscan2
- COL25A1 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67653263; called by muse, mutect2, varscan2
- COL3A1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV58586215; called by muse, mutect2, varscan2
- COL3A1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV58592665; called by muse, mutect2, varscan2
- COL4A3 | c.2679G>A p.M893I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV67417048; called by muse, mutect2, varscan2
- COL4A3 | c.3248G>A p.G1083E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59258539; called by muse, mutect2, varscan2
- COL5A3 | c.3191G>A p.G1064E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53414280; called by muse, mutect2
- COL5A3 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53414295; called by muse, varscan2
- COL6A3 | c.6548G>A p.G2183E | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55097329; called by muse, mutect2, varscan2
- COL6A3 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.433); catalogued as rs762715536, COSV55097344; called by muse, mutect2, varscan2
- COL9A3 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201337557, COSV58984270; called by muse, varscan2
- COLGALT2 | c.410C>A p.P137Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV62728348; called by muse, mutect2
- COMP | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55875475; called by muse, mutect2, varscan2
- COMP | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034028, CM984024, COSV55875482; called by muse, mutect2, varscan2
- COQ7 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58982068; called by muse, mutect2, varscan2
- CPB2 | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs777028100, COSV51675744; called by muse, mutect2, varscan2
- CPB2 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV51675751; called by muse, mutect2, varscan2
- CPLANE1 | c.8774C>T p.P2925L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57052406; called by muse, mutect2, varscan2
- CPNE7 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs772694042, COSV52014139; called by muse, mutect2, varscan2
- CPS1 | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV51815983; called by muse, mutect2, varscan2
- CPT1C | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54920494; called by muse, mutect2, varscan2
- CR1 | c.5653G>A p.G1885R | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65459975; called by muse, mutect2, varscan2
- CRACD | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV51725565; called by mutect2, varscan2
- CRB1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100958296, COSV66344110; called by muse, mutect2, varscan2
- CRB1 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66330642; called by muse, mutect2, varscan2
- CRB1 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs727503889, COSV66331588; called by muse, mutect2, varscan2
- CRHBP | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1407656696, COSV57189188; called by muse, mutect2, varscan2
- CRISPLD1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV51550640; called by muse, mutect2
- CRISPLD2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52280915; called by muse, mutect2, varscan2
- CROCC | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65011406; called by muse, mutect2, varscan2
- CRP | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54814050; called by muse, mutect2, varscan2
- CRP | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54814064; called by muse, mutect2, varscan2
- CSE1L | c.2504G>A p.G835E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53703172; called by muse, mutect2
- CSF2RB | c.201G>A p.E67= | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as rs1163499846, COSV53259003; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD1 | c.6643G>A p.G2215R (on ENST00000520002; = p.G2214R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59285987; called by muse, mutect2, varscan2
- CSMD1 | c.4928C>T p.P1643L (on ENST00000520002; = p.P1642L on NM_033225.6) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151034, COSV59346671; called by muse, varscan2
- CSMD1 | c.1570G>A p.E524K (on ENST00000520002; = p.E523K on NM_033225.6) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV59327404; called by muse, mutect2
- CSMD1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933313633, COSV68226033; called by muse, mutect2, varscan2
- CSMD2 | c.6816C>A p.F2272L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1244246983, COSV53920948, COSV53930906; called by muse, mutect2, varscan2
- CSMD3 | c.9305G>A p.W3102* (on ENST00000297405 / NM_001363185.1; = p.W2933* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as rs769777571, COSV52235692, COSV52319771; called by muse, mutect2, varscan2
- CSMD3 | c.8893C>T p.P2965S (on ENST00000297405 / NM_001363185.1; = p.P2796S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.977); catalogued as COSV52186620, COSV52219183; called by muse, mutect2, varscan2
- CSMD3 | c.4478G>A p.G1493E (on ENST00000297405 / NM_001363185.1; = p.G1389E on NM_052900.3) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs1486319011, COSV52106995, COSV99840689; called by muse, mutect2, varscan2
- CSMD3 | c.4349G>A p.G1450E (on ENST00000297405 / NM_001363185.1; = p.G1346E on NM_052900.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1255909158, COSV52235738; called by muse, varscan2
- CSMD3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52235767; called by muse, mutect2, varscan2
- CSN2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV61992374; called by muse, mutect2, varscan2
- CSNK1A1L | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV65789914; called by muse, mutect2, varscan2
- CSNK1G1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57311491; called by muse, mutect2, varscan2
- CSRNP3 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58781479; called by muse, mutect2, varscan2
- CST5 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV59014911; called by muse, mutect2, varscan2
- CSTF3 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.892); catalogued as COSV100124335, COSV60612699; called by muse, mutect2, varscan2
- CTCF | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50464834; called by muse, mutect2, varscan2
- CTNNA2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as COSV100781762, COSV63582646; called by muse, mutect2, varscan2
- CTNNA2 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV58163011; called by muse, mutect2, varscan2
- CTNNA3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV65600868; called by muse, mutect2, varscan2
- CTNNB1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767491256, COSV62707602; called by muse, mutect2, varscan2
- CTNND2 | c.2939C>T p.A980V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV58904910; called by muse, mutect2, varscan2
- CTNND2 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV58884453; called by muse, mutect2, varscan2
- CTNND2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.955); catalogued as rs911385133, COSV58868558; called by muse, mutect2, varscan2
- CTSG | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53536136; called by muse, mutect2
- CTSO | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV70809396; called by muse, mutect2, varscan2
- CTTNBP2 | c.1565C>A p.P522H | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV50419346; called by muse, mutect2, varscan2
- CUBN | c.7517A>T p.N2506I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV64720617; called by muse, mutect2, varscan2
- CUBN | c.7347G>A p.M2449I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64720623; called by muse, mutect2
- CUBN | c.6613G>A p.G2205R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140883483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.6422C>T p.P2141L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV64720636; called by muse, mutect2, varscan2
- CUBN | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV64709702; called by muse, mutect2, varscan2
- CUBN | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64720657; called by muse, mutect2, varscan2
- CUX1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782055397, COSV52891263; called by muse, mutect2, varscan2
- CWC27 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66887050; called by muse, mutect2
- CWH43 | c.2019C>T p.P673= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as rs1174274058, COSV56940845; called by muse, mutect2, varscan2
- CXCL5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV56018371; called by muse, mutect2, varscan2
- CYLD | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV61095912; called by muse, mutect2, varscan2
- CYP1A1 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs762331374, COSV65697672; called by muse, mutect2, varscan2
- CYP1B1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as rs1441119621, COSV53191844; called by muse, mutect2, varscan2
- CYP26B1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV50012957; called by muse, mutect2, varscan2
- CYP2B6 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV57844713; called by muse, mutect2, varscan2
- CYP2B6 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.132); catalogued as rs867753758, COSV57844720; called by muse, mutect2, varscan2
- CYP2C19 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV64908434; called by muse, varscan2
- CYP2C19 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV64908439; called by muse, varscan2
- CYP4X1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV64151019; called by muse, mutect2, varscan2
- CYRIB | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV67831297; called by muse, mutect2, varscan2
- CYTH2 | c.331A>C p.I111L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57309880; called by muse, mutect2
- CYTH3 | c.271A>T p.N91Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV63439781; called by muse, mutect2, varscan2
- DACH1 | c.1879-1G>A p.X627_splice (on ENST00000619232 / NM_001366712.1; = p.X373_splice on NM_004392.6) | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV57496948; called by muse, mutect2, varscan2
- DAG1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58185520; called by muse, mutect2, varscan2
- DAW1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV59367048; called by muse, mutect2, varscan2
- DBF4B | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV59258932, COSV59261867; called by muse, mutect2, varscan2
- DBX2 | c.404-2A>C p.X135_splice | Splice Site (SNP) | VAF 7/12 reads (58%) | catalogued as rs770421711, COSV60338516; called by muse, mutect2, varscan2
- DCDC1 | c.4381C>T p.P1461S (on ENST00000597505 / NM_001367979.1; = p.P568S on NM_020869.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs1322934245, COSV100338351, COSV58000686; called by muse, mutect2, varscan2
- DCDC2B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV59084889; called by muse, mutect2, varscan2
- DCLK1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55195830; called by muse, mutect2, varscan2
- DCP1B | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs766183090, COSV54970617; called by muse, mutect2, varscan2
- DCSTAMP | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV52576679; called by muse, mutect2, varscan2
- DCT | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as COSV65469945; called by muse, mutect2, varscan2
- DCUN1D2 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60261798; called by muse, mutect2, varscan2
- DDI1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as COSV100160603, COSV56384519; called by muse, mutect2, varscan2
- DDIT4L | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as COSV56767041; called by muse, varscan2
- DDR2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63372331; called by muse, mutect2, varscan2
- DDX23 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1367755264, COSV57282753; called by muse, mutect2, varscan2
- DEAF1 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV58608035; called by muse, mutect2, varscan2
- DEFB116 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 84/247 reads (34%) | catalogued as rs1281342598, COSV68722275; called by muse, mutect2, varscan2
- DENND1B | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.11); catalogued as COSV54152804; called by muse, mutect2, varscan2
- DENND1B | c.1991A>G p.K664R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.297); catalogued as COSV54152819; called by muse, mutect2, varscan2
- DENND4C | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.523); catalogued as COSV66822161; called by muse, mutect2, varscan2
- DES | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1429678305, COSV64660659; called by muse, mutect2, varscan2
- DEUP1 | c.1546A>T p.N516Y | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.203); catalogued as COSV53213947; called by muse, varscan2
- DFFA | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100986661; called by muse, mutect2, varscan2
- DGAT2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57176700; called by muse, mutect2, varscan2
- DGKB | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51784389; called by muse, mutect2, varscan2
- DGKG | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1241850596, COSV53967989; called by muse, mutect2
- DGKI | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1157602466, COSV55960446; called by muse, mutect2, varscan2
- DHTKD1 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as COSV53801935, COSV53804852; called by muse, mutect2, varscan2
- DICER1 | c.5551C>T p.R1851C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58617568; called by muse, mutect2, varscan2
- DICER1 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58623509; called by muse, mutect2, varscan2
- DIP2B | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56587282; called by muse, mutect2
- DISP3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs762363608, COSV53831379; called by muse, mutect2, varscan2
- DLG5 | c.4955C>T p.P1652L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64948711; called by muse, varscan2
- DMBT1 | c.751T>A p.Y251N | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57551010; called by muse, mutect2, varscan2
- DMD | c.6997C>T p.L2333F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58927153; called by muse, varscan2
- DMD | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63756147; called by muse, mutect2, varscan2
- DMRTC2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV54187327; called by mutect2, varscan2
- DMXL1 | c.7630C>T p.H2544Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60715998; called by muse, mutect2, varscan2
- DNAAF1 | c.428A>T p.K143I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV57577924; called by mutect2, varscan2
- DNAH1 | c.5774G>A p.G1925E | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70231794; called by muse, mutect2, varscan2
- DNAH10 | c.5011G>A p.G1671R (on ENST00000409039; = p.G1610R on NM_207437.3) | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV68996658; called by muse, mutect2, varscan2
- DNAH10 | c.6340C>T p.L2114F (on ENST00000409039; = p.L2053F on NM_207437.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68991741; called by muse, mutect2, varscan2
- DNAH11 | c.7700G>A p.G2567E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746294001, COSV60965732; called by muse, mutect2, varscan2
- DNAH17 | c.11696C>T p.T3899I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67757909; called by muse, mutect2, varscan2
- DNAH17 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV67757936; called by muse, mutect2
- DNAH3 | c.10882G>A p.G3628R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54533612; called by muse, mutect2, varscan2
- DNAH3 | c.9590C>T p.T3197I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54533632; called by muse, mutect2, varscan2
- DNAH5 | c.11443G>A p.E3815K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54232622; called by muse, varscan2
- DNAH5 | c.10963G>A p.E3655K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54237525; called by muse, mutect2, varscan2
- DNAH5 | c.6718C>A p.P2240T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV54225416, COSV54237531; called by muse, mutect2, varscan2
- DNAH5 | c.1537-1G>A p.X513_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54237537; called by muse, mutect2
- DNAH8 | c.2878T>A p.F960I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV59461795; called by muse, varscan2
- DNAH8 | c.5117A>G p.H1706R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59461827; called by muse, mutect2, varscan2
- DNAH9 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1294298953, COSV52359726; called by muse, mutect2, varscan2
- DNAH9 | c.6317G>A p.R2106K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52359734; called by muse, mutect2, varscan2
- DNAH9 | c.11734G>A p.D3912N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV52359744; called by muse, mutect2, varscan2
- DNAI4 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 31/128 reads (24%) | catalogued as COSV64030228, COSV64030526; called by muse, mutect2, varscan2
- DNAJC10 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs372451587, COSV51135757; called by muse, mutect2, varscan2
- DNAJC5G | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV56080680, COSV56081314; called by muse, mutect2, varscan2
- DOCK10 | c.4538C>T p.S1513L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51420318; called by muse, mutect2, varscan2
- DOCK10 | c.2279T>C p.I760T | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV51420333; called by muse, mutect2, varscan2
- DOCK4 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101455487, COSV70323271; called by muse, mutect2, varscan2
- DOCK5 | c.4246G>A p.E1416K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52399804, COSV52413080; called by muse, mutect2, varscan2
- DOCK6 | c.5392G>T p.V1798F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV53917775; called by muse, mutect2, varscan2
- DOCK7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV52001441; called by muse, mutect2, varscan2
- DPP10 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV59682589; called by muse, varscan2
- DPP3 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64757286; called by muse, mutect2, varscan2
- DPPA2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV72117935; called by muse, mutect2, varscan2
- DPYD | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64593381; called by muse, mutect2, varscan2
- DPYD | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV64605231; called by muse, mutect2, varscan2
- DPYSL5 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs372829541; called by muse, mutect2, varscan2
- DRD5 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV58577570; called by muse, mutect2, varscan2
- DRD5 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs867960497, COSV58578378; called by muse, mutect2, varscan2
- DSCAM | c.4541G>A p.R1514K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1186224886, COSV68030816; called by muse, mutect2, varscan2
- DSCAM | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV68030821; called by muse, mutect2, varscan2
- DSPP | c.27T>G p.I9M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56812772; called by muse, mutect2, varscan2
- DST | c.18574G>A p.E6192K (on ENST00000361203 / NM_001374722.1; = p.E3889K on NM_015548.5) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as rs756660501, COSV54999095; called by muse, mutect2, varscan2
- DTX2 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56859972, COSV56862738; called by mutect2, varscan2
- DUSP15 | c.373A>G p.N125D (on ENST00000278979 / NM_001320479.1; = p.N128D on NM_080611.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54067127; called by muse, mutect2, varscan2
- DYNC1H1 | c.11211A>T p.E3737D | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64139044; called by muse, mutect2, varscan2
- DYNC1I1 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV100268907, COSV61465419; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs1190501973, COSV50755271; called by muse, mutect2, varscan2
- DYNC2H1 | c.9730C>T p.L3244F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV62097921, COSV62099286; called by muse, mutect2, varscan2
- DYNC2I1 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV68105790; called by muse, mutect2, varscan2
- DYRK1A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); catalogued as COSV58295244; called by muse, mutect2, varscan2
- EBF1 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV58185758; called by muse, mutect2, varscan2
- ECPAS | c.2777G>A p.G926E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52201589; called by muse, mutect2, varscan2
- ECPAS | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52201606; called by muse, mutect2, varscan2
- EGR2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1564706128, COSV54346185, COSV99654131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGR2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54347621; called by mutect2, varscan2
- EIF2AK4 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254425869, COSV55465794; called by muse, mutect2, varscan2
- EIF4A1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs199974690, COSV53441875; called by muse, mutect2, varscan2
- ELFN2 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.929); catalogued as rs770420117, COSV68744909; called by mutect2, varscan2
- EMILIN2 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV54425238; called by muse, mutect2, varscan2
- ENAM | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV68536486; called by muse, mutect2, varscan2
- ENPP2 | c.1087G>A p.E363K (on ENST00000075322 / NM_001040092.3; = p.E415K on NM_006209.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50021820; called by muse, mutect2, varscan2
- ENPP4 | c.630A>G p.I210M | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV58089483; called by muse, mutect2, varscan2
- ENTPD3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1213888544, COSV57195290; called by muse, mutect2, varscan2
- ENTPD6 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.173); catalogued as COSV61751941; called by muse, mutect2, varscan2
- EP400 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV57777861; called by muse, mutect2, varscan2
- EPB41L4A | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54874335; called by muse, mutect2, varscan2
- EPDR1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52260716; called by muse, mutect2, varscan2
- EPHA2 | c.2520G>A p.M840I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as rs1434356630, COSV64453899; called by muse, mutect2, varscan2
- EPHA5 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs1198864954, COSV56656026; called by muse, mutect2, varscan2
- EPHA7 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465960814, COSV65178482; called by muse, mutect2
- EPHA7 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760168204, COSV65168519; called by muse, mutect2, varscan2
- EPHA7 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65168638; called by muse, mutect2, varscan2
- EPHB2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV65863892; called by muse, mutect2, varscan2
- EPHX4 | c.315C>T p.F105= | Splice Region (SNP) | VAF 18/54 reads (33%) | catalogued as COSV64889651, COSV64889718; called by muse, mutect2, varscan2
- EPOR | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55800899; called by muse, mutect2, varscan2
- EPX | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56597733; called by muse, mutect2, varscan2
- ERBB4 | c.3073C>T p.P1025S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV61501152; called by muse, mutect2, varscan2
- ERICH5 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100582893, COSV59316364; called by muse, mutect2, varscan2
- ERMAP | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV100072135, COSV60274921; called by muse, mutect2, varscan2
- ERMARD | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64648393; called by muse, mutect2, varscan2
- ERN1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs1567858821, COSV70503214; called by muse, mutect2, varscan2
- ERN1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV70503221; called by muse, mutect2, varscan2
- ESR1 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as COSV52782329; called by muse, mutect2, varscan2
- EVC2 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs144270330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI5 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.023); catalogued as COSV64828467; called by muse, mutect2, varscan2
- EXO1 | c.2007A>C p.E669D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV62218375; called by muse, mutect2, varscan2
- EXOC3L2 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348252167, COSV52973648; called by muse, mutect2, varscan2
- EXOG | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs866211020, COSV55063963; called by muse, mutect2, varscan2
- EYA4 | c.1883C>T p.S628F (on ENST00000531901 / NM_001301013.1; = p.S622F on NM_004100.5) | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62056315; called by muse, mutect2, varscan2
- F10 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60645185; called by muse, mutect2
- F2RL3 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV50185916; called by muse, mutect2, varscan2
- F5 | c.4058G>A p.G1353D | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV63125812; called by muse, mutect2, varscan2
- FADS1 | c.864C>A p.D288E | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV63520408, COSV63520816; called by muse, mutect2, varscan2
- FAM131A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.003); catalogued as COSV55602506; called by muse, mutect2, varscan2
- FAM131B | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV58371888; called by muse, mutect2, varscan2
- FAM135B | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV52737724, COSV99424890, COSV99426619; called by muse, mutect2, varscan2
- FAM135B | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1379687270, COSV50529580, COSV50530613; called by muse, varscan2
- FAM155A | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV65571419; called by muse, mutect2, varscan2
- FAM161A | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs776991876, COSV56766727; called by muse, mutect2, varscan2
- FAM184A | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV58856097; called by muse, mutect2, varscan2
- FAM186B | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57722226; called by muse, mutect2, varscan2
- FAM227B | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs905733396, COSV100175471, COSV54814391; called by mutect2, varscan2
- FAM234A | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770705186, COSV56996162; called by muse, mutect2, varscan2
- FAM24A | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64405892, COSV64406046; called by muse, mutect2, varscan2
- FAM47C | c.2647C>T p.Q883* | Nonsense Mutation (SNP) | VAF 53/72 reads (74%) | catalogued as COSV63728257; called by muse, mutect2, varscan2
- FAM53C | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV53511441, COSV53512274; called by muse, mutect2, varscan2
- FAM71C | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1365642247, COSV60943733; called by muse, mutect2, varscan2
- FARP1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60341580; called by muse, mutect2, varscan2
- FAS | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.072); catalogued as COSV58239396; called by muse, mutect2, varscan2
- FASLG | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV60680460; called by muse, mutect2, varscan2
- FAT1 | c.3286C>T p.R1096* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs1358297166, COSV71672426; called by muse, mutect2, varscan2
- FAT1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV71674681; called by muse, mutect2, varscan2
- FAT2 | c.4620G>A p.W1540* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55824030; called by muse, mutect2
- FAT2 | c.4619G>A p.W1540* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55824040; called by muse, mutect2
- FAT2 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV55824065; called by muse, mutect2
- FAT3 | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.792); catalogued as COSV53095684, COSV53138726; called by muse, mutect2, varscan2
- FAT3 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53137083; called by muse, mutect2, varscan2
- FAT3 | c.5913G>A p.M1971I | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53138763; called by muse, mutect2, varscan2
- FAT3 | c.11884G>A p.V3962M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs1001382721, COSV53138826; called by muse, mutect2, varscan2
- FAT3 | c.12484C>T p.L4162F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV53138861; called by mutect2, varscan2
- FBN1 | c.2644G>T p.A882S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV57322698; called by muse, mutect2, varscan2
- FBN1 | c.249C>T p.P83= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as COSV57322708; called by mutect2, varscan2
- FBN2 | c.4878C>T p.S1626= | Splice Region (SNP) | VAF 88/225 reads (39%) | catalogued as COSV52526574; called by muse, mutect2, varscan2
- FBXL6 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV57352578; called by muse, mutect2, varscan2
- FBXO22 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs372221349, COSV100380724, COSV57616882; called by muse, mutect2, varscan2
- FBXO30 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52791701; called by muse, mutect2, varscan2
- FBXO38 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764491940, COSV57029286; called by muse, mutect2, varscan2
- FBXO7 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.957); catalogued as COSV56679707; called by muse, mutect2, varscan2
- FBXW10 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as rs1269951623, COSV57319553, COSV57319757; called by muse, mutect2, varscan2
- FBXW7 | c.535C>T p.R179C (on ENST00000281708 / NM_001349798.2; = p.R99C on NM_018315.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs1207004877, COSV55932507; called by mutect2, varscan2
- FBXW8 | c.946G>A p.E316K (on ENST00000309909; = p.E354K on NM_012174.1) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV59301371; called by muse, mutect2, varscan2
- FBXW8 | c.1357C>T p.R453C (on ENST00000309909; = p.R491C on NM_012174.1) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs569559960, COSV59296965; called by muse, mutect2, varscan2
- FCAMR | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV61368465; called by muse, mutect2, varscan2
- FCAR | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV62030495; called by muse, mutect2, varscan2
- FCRL2 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV63834214; called by muse, mutect2, varscan2
- FCRL4 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs777588327, COSV54863730; called by muse, mutect2, varscan2
- FCRL5 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62516962; called by muse, mutect2, varscan2
- FCRL6 | c.536G>A p.W179* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58939858; called by muse, mutect2, varscan2
- FDXACB1 | c.1048T>A p.S350T | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52789477; called by muse, mutect2, varscan2
- FERMT2 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58408075; called by muse, mutect2, varscan2
- FFAR3 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV59909343; called by muse, mutect2, varscan2
- FGA | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1184066844, COSV57397044; called by muse, mutect2, varscan2
- FGB | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.104); catalogued as rs1457983098, COSV57418877; called by muse, mutect2, varscan2
- FGD5 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53246668; called by muse, mutect2, varscan2
- FHDC1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753783811, COSV52597165; called by muse, mutect2, varscan2
- FIGN | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV60769151; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, varscan2
- FLG | c.10741C>T p.H3581Y | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV64244434; called by muse, mutect2, varscan2
- FLG | c.8468G>A p.G2823E | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV64244380; called by muse, mutect2, varscan2
- FLG2 | c.4693G>A p.G1565R | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs781511680, COSV66170404; called by muse, mutect2, varscan2
- FLNA | c.7900G>A p.D2634N (on ENST00000369850 / NM_001110556.2; = p.D2626N on NM_001456.3) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV61046828; called by muse, mutect2, varscan2
- FLNA | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61046847; called by muse, mutect2, varscan2
- FLNC | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1370708709, COSV57959359; called by muse, mutect2, varscan2
- FLNC | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs752448040, COSV57951263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.5305G>A p.E1769K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV57959371; called by muse, mutect2, varscan2
- FMN2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV60427033, COSV60437540; called by muse, mutect2, varscan2
- FMN2 | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.078); catalogued as COSV60415983; called by muse, mutect2, varscan2
- FMN2 | c.4637T>A p.F1546Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV60429465, COSV60439128; called by muse, mutect2, varscan2
- FMO4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.36); catalogued as rs1338446961, COSV63001480; called by muse, mutect2, varscan2
- FMO5 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.866); catalogued as COSV54208376; called by muse, mutect2, varscan2
- FMOD | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV61610302, COSV61610630; called by muse, mutect2, varscan2
- FNDC1 | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV51942356; called by muse, mutect2, varscan2
- FNDC1 | c.3593C>T p.S1198F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV51942365; called by muse, mutect2, varscan2
- FOXN3 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868489832, COSV54312498; called by muse, mutect2, varscan2
- FPGS | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV64675720; called by mutect2, varscan2
- FPGT | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV63843026; called by muse, mutect2, varscan2
- FREM1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as rs1292738426, COSV66519456; called by muse, mutect2, varscan2
- FRMD1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV51963299; called by muse, mutect2, varscan2
- FRMD6 | c.887C>T p.S296F (on ENST00000344768 / NM_001267046.2; = p.S288F on NM_152330.4) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61089414; called by muse, mutect2, varscan2
- FRMPD2 | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59716700, COSV59720103; called by muse, mutect2, varscan2
- FRY | c.6706C>T p.P2236S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV66573682; called by muse, mutect2, varscan2
- FSCB | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1566598890, COSV61218799; called by muse, mutect2, varscan2
- FSCB | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV61217521; called by muse, mutect2, varscan2
- FSCN3 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV50001441; called by muse, mutect2, varscan2
- FSTL1 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55234726; called by muse, mutect2, varscan2
- FSTL5 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs199735797, COSV60186524, COSV60208227; called by muse, mutect2, varscan2
- FTMT | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58420771; called by muse, varscan2
- FTMT | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001617936, COSV58420784; called by muse, varscan2
- FUT8 | c.1712C>T p.P571L (on ENST00000360689 / NM_001371534.1; = p.P408L on NM_004480.4) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV61287311; called by muse, varscan2
- FYB1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs374928648; called by muse, mutect2, varscan2
- FYB1 | c.701A>T p.K234I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60950607; called by muse, mutect2, varscan2
- FZD9 | c.815T>A p.M272K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60670695; called by muse, mutect2, varscan2
- GABRA2 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs200987678, COSV62916606; called by muse, mutect2, varscan2
- GABRB2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV50924256; called by muse, mutect2, varscan2
- GABRG1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54957475; called by muse, mutect2, varscan2
- GAD1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs150945113; called by muse, mutect2, varscan2
- GAD1 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as COSV64026669; called by muse, mutect2, varscan2
- GADL1 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV56981668; called by muse, mutect2, varscan2
- GADL1 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778209588, COSV56981686; called by muse, mutect2, varscan2
- GALNT10 | c.1654-1G>A p.X552_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51729667; called by muse, mutect2, varscan2
- GALNT10 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.962); catalogued as COSV51729677; called by muse, mutect2, varscan2
- GANC | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | PolyPhen benign (0); catalogued as COSV58810111; called by muse, mutect2, varscan2
- GAPT | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100576291, COSV59247139; called by muse, mutect2, varscan2
- GARRE1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV55101213, COSV55105040; called by muse, mutect2, varscan2
- GATA6 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV52526590; called by muse, mutect2, varscan2
- GBA3 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV72437959; called by muse, mutect2, varscan2
- GBF1 | c.5422C>T p.P1808S (on ENST00000369983 / NM_001377137.1; = p.P1807S on NM_004193.3) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64146685; called by muse, mutect2, varscan2
- GCK | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV60787325; called by muse, mutect2, varscan2
- GCN1 | c.2579G>A p.G860E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV56110652; called by muse, mutect2, varscan2
- GCN1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs748255642, COSV56110663; called by muse, mutect2, varscan2
- GCNT2 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV65457789; called by muse, mutect2, varscan2
- GDAP1L1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs777303313, COSV61157481; called by muse, mutect2, varscan2
- GDPD3 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53774813; called by muse, mutect2, varscan2
- GEMIN5 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760815734, COSV53562270; called by muse, mutect2, varscan2
- GFPT2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV53809955; called by muse, mutect2, varscan2
- GFRAL | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231832, COSV61231991; called by muse, mutect2, varscan2
- GGT7 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60539971; called by muse, mutect2, varscan2
- GIMAP1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV56188944; called by mutect2, varscan2
- GJA10 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV65355572; called by muse, mutect2, varscan2
- GJA8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782805555, COSV53789424; called by muse, mutect2, varscan2
- GJB4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV58356587; called by muse, mutect2, varscan2
- GK2 | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750942911, COSV62627643; called by muse, mutect2, varscan2
- GLDN | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59089783; called by muse, mutect2, varscan2
- GLI2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV58045830; called by muse, mutect2, varscan2
2,900 further variants in this file (1,590 protein-altering or splice-affecting, 1,219 silent, 91 other) are not listed here.
